Gene-level copy-number profile of tumor specimen ALCH-B1PR-TTP1-A from ALCHEMIST case ALCH-B1PR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 83.0 years (30,330 days).
Specimen ALCH-B1PR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 03b8cfdc-09cc-4df3-ba25-c8a5175688f1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1PR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/4885b27e-6766-4866-b60c-2fd4f2e3213a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 97; copy number 1: 1,193; copy number 2: 54,959; copy number 3: 2,069; copy number 4: 70; copy number 5: 3; copy number 8: 1; copy number 12: 1; copy number 22: 3.

Homozygous deletions (total copy number 0; autosomes only): 97 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:112,693,688–112,711,433, 3 genes (within-gene range 0–2): AL603832.1, RHOC, AL603832.3.
- chr2:96,112,876–96,147,012, 4 genes: ADRA2B, ASTL, DUSP2, AC012307.1.
- chr2:130,139,287–130,182,750, 2 genes (within-gene range 0–2): CCDC74B, SMPD4.
- chr2:218,398,256–218,405,941, 3 genes: CTDSP1, AC021016.2, MIR26B.
- chr5:1,050,384–1,112,063, 2 genes (within-gene range 0–1): SLC12A7, MIR4635.
- chr5:176,810,519–176,880,898, 1 gene (within-gene range 0–2): UNC5A.
- chr7:99,416,739–99,466,197, 5 genes (within-gene range 0–1): PTCD1, ATP5MF-PTCD1, CPSF4, AC073063.1, ATP5MF.
- chr8:143,603,210–143,609,773, 1 gene (within-gene range 0–2): PYCR3.
- chr9:129,803,157–129,811,281, 1 gene: TOR1B.
- chr9:130,651,799–130,652,383, 1 gene: AL359092.2.
- chr10:72,332,830–72,355,149, 1 gene: DNAJB12.
- chr14:92,923,150–92,935,285, 1 gene: CHGA.
- chr14:102,501,676–102,509,799, 2 genes (within-gene range 0–2): RNU6-244P, ANKRD9.
- chr14:104,681,146–104,722,535, 2 genes (within-gene range 0–2): INF2, AL583722.3.
- chr14:105,140,982–105,168,824, 2 genes (within-gene range 0–1): JAG2, MIR6765.
- chr15:25,172,635–25,243,695, 39 genes (within-gene range 0–2): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40.
- chr15:78,759,206–78,811,464, 1 gene (within-gene range 0–2): ADAMTS7.
- chr16:2,025,356–2,039,026, 1 gene: SLC9A3R2.
- chr16:89,906,157–89,938,761, 5 genes (within-gene range 0–2): AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3.
- chr17:18,225,635–18,244,875, 1 gene (within-gene range 0–2): LLGL1.
- chr17:77,373,818–77,377,236, 1 gene (within-gene range 0–2): AC111182.1.
- chr17:77,396,984–77,397,054, 1 gene (within-gene range 0–2): MIR4316.
- chr18:79,420,836–79,422,780, 1 gene (within-gene range 0–2): AC018445.3.
- chr19:7,868,719–7,903,542, 6 genes: PRR36, AC010336.3, LYPLA2P2, 5S_rRNA, LRRC8E, AC010336.1.
- chr20:63,939,829–63,956,985, 4 genes (within-gene range 0–1): UCKL1, MIR1914, MIR647, UCKL1-AS1.
- chr20:63,974,116–63,980,008, 1 gene (within-gene range 0–1): SAMD10.
- chr20:64,073,181–64,079,988, 2 genes: RGS19, MIR6813.
- chr22:46,112,749–46,113,768, 3 genes (within-gene range 0–2): MIRLET7A3, MIR4763, MIRLET7B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:136,329,441–136,329,913, 1 gene, copy number 5: UBBP1.
- chr7:74,773,962–74,789,376, 1 gene, copy number 12: NCF1.
- chr13:79,311,824–79,406,477, 2 genes, copy number 5 (within-gene range 2–5): RBM26, RNA5SP33.
- chr21:44,107,373–44,131,181, 1 gene, copy number 8: PWP2.
- chr21:44,158,740–44,194,338, 3 genes, copy number 22: LINC01678, AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 1,139. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
